Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA4X, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA4X-01A (Primary Tumor).

Histopathology Histopathology

Specimen Comments

SPECIMEN

- 1 - Bladder tumour.
- 2 - Base of tumour.
- 3 - Bladder neck.

CLINICAL DETAILS

New solid bladder tumour.

MACROSCOPY

- 1 - 5g of firm and friable tissue.
- 2 - 4 pieces of tissue, the largest 4 mm.
- 3 - 2 pieces of tissue, the largest 6 mm.

MICROSCOPY

Part 1

Grade: 3 poorly differentiated with necrosis.
Growth pattern: Solid with a very focal papillary area.
Type: Transitional cell carcinoma.
Muscularis propria present: Yes.
Stromal invasion: Invasion of muscularis propria (pT2).
Vascular channel invasion: Not identified.
Background urothelium: Carcinoma in situ is present in flat urothelium.
Summary: Transitional cell carcinoma G3 pT2, CIS.

Part 2

All the tissue was processed and consists of 4 pieces of bladder wall with a heavy acute on chronic inflammatory cell infiltrate. Some areas there is nuclear smearing due to crush artefact but there is no morphologically evidence of invasive transitional cell carcinoma in the multiple tissue planes examined. No immunohistochemistry has been done.

Part 3

Bladder wall tissue with no evidence of invasive transitional cell carcinoma. No lining epithelium was included in the biopsy.

SUMMARY

Transitional cell carcinoma G3 pT2, CIS.

Ref:

Pathologists -

CLCE ICD O-3
Carcinoma, urothelial NOS 8120/3
path Carcinoma, transitional cell NOS 8120/3
Site: 4 Bladder NOS 067.9
Op 4/30/14

Source: NCI Genomic Data Commons file c9920670-27cb-4f8d-a068-36f70b672291 (TCGA-ZF-AA4X.56AEE38E-1301-436B-91CE-BCDB523A56E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).